TARGET case TARGET-40-PAMYYJ — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bfe96ee9-2926-57a1-b10a-737af58bbdc9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 17 years; Vital status: Dead; Days to death: 271 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 17.7 years (6,477 days); Year of diagnosis: 2004; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 271 days; Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 67.
   Treatment given: Protocol identifier: AOST0121.

Follow-up (2 entries)
- Days to follow up: 128 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 128 days; Days to first event: 128 days; First event: Relapse.
- Days to follow up: 271 days; Year of follow up: 2005.

Biospecimens (2 samples)
- Sample TARGET-40-PAMYYJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PAMYYJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 271
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Leg NOS
- Site of initial relapse: Lung

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAMYYJ-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 95
- % Non Tumor Nuclei: Top from Biopsy: 5
- % Cellular Tumor: Top from Biopsy: 91
- % Normal: Top from Biopsy: 2
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 7
- % Tumor Nuclei: Bottom from Biopsy: 80
- % Non Tumor Nuclei: Bottom from Biopsy: 20
- % Cellular Tumor: Bottom from Biopsy: 39
- % Normal: Bottom from Biopsy: 50
- % Stroma: Bottom from Biopsy: 10
- % Necrosis: Bottom from Biopsy: 1
- PASS/FAIL: pass
